Gene-level copy-number profile of tumor specimen TCGA-F5-6702-01A from TCGA case TCGA-F5-6702, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IVA; Age at diagnosis: 71.5 years (26,123 days).
Specimen TCGA-F5-6702-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.c4076f56-1b06-46de-a38d-405d7b138676.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-F5-6702-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9bf43e89-4bcf-4856-8ef5-b92adbf31086

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 10,693; copy number 2: 35,558; copy number 3: 10,379; copy number 4: 3,109; copy number 6: 11; copy number 15: 60.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-F5-6702-01A-11D-1825-01): tumor purity 0.33, ploidy 3.68, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:42,649,520–43,499,836, 5 genes: AC084335.1, RIT2, AC100779.1, SYT4, AC022743.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 71 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:26,488,952–29,505,947, 60 genes, copy number 15 (within-gene range 3–15): AL353789.1, WASF3, RPS3AP44, WASF3-AS1, AL159978.1, GPR12, FGFR1OP2P1, AL160035.1, RPS21P8, RPS20P32, USP12, AL158062.1, USP12-AS1, USP12-AS2, LINC02340, LINC00412, RPL21, SNORD102, SNORA27, RASL11A, RNU6-70P, LINC01079, RNY1P1, GTF3A, MTIF3, RNU6-63P, LNX2, POLR1D, AL136439.1, NPM1P4, GSX1, PLUT, RNU6-73P, PDX1, ATP5F1EP2, LINC00543, CDX2, URAD, RN7SL272P, FLT3, KATNBL1P1, CHCHD2P8, PAN3-AS1, PAN3, EEF1A1P3, RNU6-82P, FLT1, AL139005.1, EIF4A1P7, Y_RNA, POMP, SLC46A3, RNU6-53P, CYP51A1P2, AL359741.1, POM121L13P, MTUS2, MTUS2-AS2, GAPDHP69, AL596092.1.
- chr13:91,023,732–91,354,579, 11 genes, copy number 6: BRK1P2, LINC00380, LINC00379, PPIAP23, MIR17HG, MIR17, MIR18A, MIR19A, MIR20A, MIR19B1, MIR92A1.

Autosomal genes at a single copy (total copy number 1): 10,686. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
